Somatic mutation profile of tumor specimen TCGA-B0-4815-01A (aliquot TCGA-B0-4815-01A-01D-1501-10) from TCGA case TCGA-B0-4815, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 65.4 years (23,873 days).
Specimen TCGA-B0-4815-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27adbc59-fb73-4cbd-a87b-7760d9bec80e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-4815-11A (Solid Tissue Normal), aliquot TCGA-B0-4815-11A-02D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e321329d-9a77-49e8-a1ae-8c1a4d46af5e

The open-access MAF lists 76 somatic variants for this specimen: 56 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 19, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAGAB | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 78/410 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as rs779782680, COSV56016015; called by muse, mutect2, varscan2
- ARMH3 | c.388T>C p.F130L | Missense Mutation (SNP) | VAF 59/391 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.495); catalogued as COSV60750410; called by muse, mutect2, varscan2
- ATP8B3 | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185225335, COSV59540331; called by muse, mutect2, varscan2
- BAZ2B | c.4693C>G p.R1565G | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV58596127, COSV58611614; called by muse, mutect2
- C4BPA | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.917); catalogued as rs200186980, COSV100891191, COSV65535755; called by muse, varscan2
- CCDC18 | c.567G>C p.L189F | Missense Mutation (SNP) | VAF 20/255 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58141458, COSV58143320; called by muse, mutect2
- CD3E | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62345265; called by muse, mutect2, varscan2
- CD3E | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62345271; called by muse, mutect2, varscan2
- CDC73 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 57/455 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV66465084; called by muse, mutect2, varscan2
- CHD6 | c.1010A>G p.E337G | Missense Mutation (SNP) | VAF 106/379 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV58554082; called by muse, mutect2, varscan2
- CMYA5 | c.8843C>T p.S2948F | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV71404146; called by muse, mutect2
- EXOSC10 | c.2615G>C p.G872A (on ENST00000376936 / NM_001001998.3; = p.G847A on NM_002685.4) | Missense Mutation (SNP) | VAF 55/278 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.062); catalogued as COSV58663758; called by muse, mutect2, varscan2
- FBXO39 | c.1015A>C p.T339P | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV58621061; called by muse, mutect2, varscan2
- FGD5 | c.2305G>A p.A769T | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.421); catalogued as COSV53237649; called by mutect2, varscan2
- FIG4 | c.457A>G p.I153V | Missense Mutation (SNP) | VAF 92/572 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV57785188; called by muse, mutect2, varscan2
- GABRA1 | c.7A>T p.K3* | Nonsense Mutation (SNP) | VAF 55/278 reads (20%) | catalogued as COSV50099002; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2236C>A p.L746M (on ENST00000265755 / NM_016328.3; = p.L731M on NM_005685.4) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56084546; called by muse, mutect2, varscan2
- GTPBP2 | c.773T>A p.F258Y | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV61075677; called by muse, mutect2, varscan2
- IQGAP2 | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 71/501 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57168287; called by muse, mutect2
- KEAP1 | c.1630T>C p.W544R | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50262319; called by muse, mutect2
- KRT79 | c.1367+1G>A p.X456_splice | Splice Site (SNP) | VAF 6/31 reads (19%) | catalogued as rs763065674, COSV57938444; called by muse, mutect2, varscan2
- LGI2 | c.188T>C p.I63T | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV66122367; called by muse, mutect2, varscan2
- MAP3K5 | c.2457G>T p.K819N | Missense Mutation (SNP) | VAF 98/570 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62887194; called by muse, varscan2
- MED10 | c.323T>A p.L108Q | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.995); catalogued as rs753793956, COSV55385698; called by muse, mutect2, varscan2
- MTFR1L | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65355486; called by muse, mutect2, varscan2
- NDRG1 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 77/330 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60482559; called by muse, mutect2, varscan2
- PABPN1L | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs981857240, COSV56350977; called by muse, mutect2, varscan2
- PAX8 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as rs1397854984, COSV54506516; called by muse, mutect2
- PBRM1 | c.1112C>G p.S371* | Nonsense Mutation (SNP) | VAF 22/123 reads (18%) | catalogued as COSV56262186; called by muse, mutect2, varscan2
- PGPEP1L | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs369052790, COSV51270773; called by muse, mutect2, varscan2
- PHF3 | c.5672G>A p.R1891Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as rs1341703095, COSV50313503; called by muse, mutect2
- POTEF | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as rs368389320; called by muse, mutect2, varscan2
- PRKACA | c.954G>C p.K318N | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV54114687; called by muse, mutect2, varscan2
- PSMB11 | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.954); catalogued as COSV68429570; called by muse, mutect2, varscan2
- RBBP5 | c.44A>G p.E15G | Missense Mutation (SNP) | VAF 106/680 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52702891; called by muse, mutect2, varscan2
- RHBDD2 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.061); catalogued as COSV99138189; called by muse, mutect2, varscan2
- ROS1 | c.4334T>A p.L1445Q | Missense Mutation (SNP) | VAF 100/648 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63851471; called by muse, mutect2, varscan2
- SCAF11 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 43/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56976420; called by muse, mutect2, varscan2
- SCARF2 | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.23); catalogued as COSV56731157; called by muse, mutect2, varscan2
- SLC19A3 | c.827A>C p.K276T | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.14); catalogued as COSV51451476; called by muse, mutect2, varscan2
- SLC9C2 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 61/458 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs528983665, COSV62943283; called by muse, mutect2, varscan2
- SPRED1 | c.781T>C p.Y261H | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54434434; called by muse, mutect2, varscan2
- SRSF1 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV51964169; called by muse, mutect2, varscan2
- TAAR2 | c.392T>C p.I131T (on ENST00000367931 / NM_001033080.1; = p.I86T on NM_014626.3) | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV51578431; called by muse, mutect2, varscan2
- TCF20 | c.2738G>C p.G913A | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59488584; called by muse, mutect2, varscan2
- TMEM117 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 61/483 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.981); catalogued as COSV56895178; called by muse, mutect2, varscan2
- TMEM59 | c.662T>G p.F221C | Missense Mutation (SNP) | VAF 86/434 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.205); catalogued as COSV52372787; called by muse, mutect2, varscan2
- WAC | c.1395C>G p.I465M | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as COSV61566771, COSV61568010; called by muse, mutect2
- ZNF629 | c.866C>G p.P289R | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52697509; called by muse, mutect2
- ZNF740 | c.201T>G p.D67E | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV57241458; called by muse, mutect2
- ZNF846 | c.1393C>G p.L465V | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV67411797; called by muse, mutect2, varscan2
- ACACA | c.5786T>C p.V1929A | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ATAD2 | c.2672del p.L891Yfs*46 | Frame Shift Del (DEL) | VAF 38/283 reads (13%) | called by mutect2, pindel, varscan2
- MAP4K5 | c.1874del p.C625Ffs*3 | Frame Shift Del (DEL) | VAF 108/486 reads (22%) | called by mutect2, pindel, varscan2
- RNASEL | c.1139del p.Y380Sfs*10 | Frame Shift Del (DEL) | VAF 18/164 reads (11%) | called by mutect2, pindel, varscan2
- TPTE | c.1368C>A p.N456K (on ENST00000618007 / NM_199261.4; = p.N438K on NM_199259.4) | Missense Mutation (SNP) | VAF 52/716 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2
- B3GNT6 | c.51C>T p.L17= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs1555027383, COSV62827838; called by muse, mutect2, varscan2
- DGKK | c.1068C>A p.I356= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as COSV65706448; called by muse, mutect2, varscan2
- ECPAS | c.1287T>A p.T429= | Silent (SNP) | VAF 63/225 reads (28%) | catalogued as COSV52192098; called by muse, mutect2, varscan2
- GSTA2 | c.67C>T p.L23= | Silent (SNP) | VAF 55/307 reads (18%) | catalogued as rs757047103, COSV72414596; called by muse, mutect2, varscan2
- JUN | c.834C>G p.A278= | Silent (SNP) | VAF 40/226 reads (18%) | catalogued as COSV64664185; called by muse, mutect2
- KCNK9 | c.564C>T p.H188= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as rs1297426024, COSV57278406; called by muse, mutect2
- MFSD1 | c.1377A>T p.I459= | Silent (SNP) | VAF 80/414 reads (19%) | catalogued as COSV51839182; called by muse, mutect2, varscan2
- MGAM | c.4143C>T p.A1381= | Silent (SNP) | VAF 33/314 reads (11%) | catalogued as COSV72073694; called by muse, mutect2, varscan2
- NRXN2 | c.2301A>C p.G767= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV55447691; called by muse, mutect2, varscan2
- OR10J5 | c.558T>G p.L186= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as COSV58384900; called by muse, mutect2, varscan2
- P2RX4 | c.210C>T p.G70= | Silent (SNP) | VAF 82/570 reads (14%) | catalogued as rs1160649171, COSV58742108; called by muse, mutect2, varscan2
- PKD2L2 | c.1419T>G p.T473= | Silent (SNP) | VAF 213/1415 reads (15%) | catalogued as COSV51794833; called by muse, mutect2, varscan2
- PNLDC1 | c.459G>C p.V153= | Silent (SNP) | VAF 16/266 reads (6%) | catalogued as COSV51703881; called by muse, mutect2
- RHBDD2 | c.987C>T p.G329= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV50086748; called by muse, mutect2, varscan2
- SLC26A5 | c.1980G>T p.L660= | Silent (SNP) | VAF 28/157 reads (18%) | catalogued as COSV59698308; called by muse, mutect2
- SLC35F3 | c.1113C>T p.L371= (on ENST00000366617 / NM_001300845.1; = p.L440= on NM_173508.4) | Silent (SNP) | VAF 44/247 reads (18%) | catalogued as COSV64018384; called by muse, mutect2, varscan2
- SLC9A3 | c.1306C>T p.L436= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs150200197; called by muse, mutect2, varscan2
- TRABD2A | c.903C>A p.I301= (on ENST00000409520 / NM_001277053.2; = p.I252= on NM_001080824.3) | Silent (SNP) | VAF 39/245 reads (16%) | catalogued as COSV59101779; called by muse, mutect2, varscan2
- UGT2A3 | c.48C>T p.F16= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV52358905; called by muse, mutect2, varscan2
- SSX9P | n.461C>A | RNA (SNP) | VAF 45/392 reads (11%) | called by muse, mutect2, varscan2
